Gene-level copy-number profile of tumor specimen TCGA-DX-A240-01A from TCGA case TCGA-DX-A240, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Spermatic cord; Age at diagnosis: 51.3 years (18,721 days).
Specimen TCGA-DX-A240-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.c6f8a3e8-59d4-4096-9e11-d699510f99fd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A240-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/960c2d62-e46c-4a13-b024-7c672fd6ba0f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,146; copy number 2: 53,908; copy number 3: 2,314; copy number 4: 137; copy number 5: 330; copy number 6: 177; copy number 7: 203; copy number 8: 105; copy number 9: 42; copy number 10: 48; copy number 11: 112; copy number 12: 64; copy number 13: 55; copy number 14: 3; copy number 15: 16; copy number 16: 65; copy number 17: 31; copy number 18: 16; copy number 19: 4; copy number 20: 38; copy number 23: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A240-01A-32D-A27O-01): tumor purity 0.74, ploidy 2.11, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,064 genes in 65 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,419,053–147,699,335, 9 genes, copy number 12: OR13Z1P, Y_RNA, OR13Z2P, OR13Z3P, BCL9, AC242628.1, ACP6, RN7SL261P, AC241644.1.
- chr1:149,903,318–150,164,720, 8 genes, copy number 10 (within-gene range 3–10): SV2A, SF3B4, MTMR11, OTUD7B, AC244033.2, AC244033.1, VPS45, PLEKHO1.
- chr1:159,704,983–159,782,543, 4 genes, copy number 19: CRPP1, CRP, AL445528.1, DUSP23.
- chr1:159,851,906–160,262,549, 24 genes, copy number 10 (within-gene range 2–10): AL590560.1, VSIG8, AL590560.3, CFAP45, MIR4259, AL590560.5, AL590560.4, TAGLN2, IGSF9, SLAMF9, LINC01133, AL513485.1, KCNJ10, AL513302.1, PIGM, AL121987.1, KCNJ9, IGSF8, ATP1A2, ATP1A4, CASQ1, AL121987.2, PEA15, DCAF8.
- chr1:160,608,106–161,379,358, 47 genes, copy number 11 (within-gene range 2–11): SLAMF1, SETP9, AL121985.1, CD48, SLAMF7, AL121985.3, AL121985.2, LY9, CD244, PPIAP37, ITLN1, AL354714.2, AL354714.3, AL354714.1, AL354714.4, ITLN2, F11R, AL591806.2, GLRX5P2, TSTD1, USF1, ARHGAP30, NECTIN4, NECTIN4-AS1, KLHDC9, PFDN2, NIT1, DEDD, AL591806.1, UFC1, AL590714.1, USP21, PPOX, B4GALT3, ADAMTS4, NDUFS2, FCER1G, APOA2, TOMM40L, MIR5187, NR1I3, PCP4L1, MPZ, SDHC, CFAP126, AL592295.6, RRM2P2.
- chr1:168,898,136–172,468,831, 83 genes, copy number 7–16 (broad region; genes not listed).
- chr3:88,601,061–90,261,708, 11 genes, copy number 7: NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr6:88,177,804–88,442,928, 4 genes, copy number 5 (within-gene range 2–5): AL139042.1, AL121835.1, ACTBP8, AL139090.1.
- chr6:92,002,610–92,388,827, 4 genes, copy number 5–6 (within-gene range 1–6): AL590814.1, RPL5P19, U3, AL133457.1.
- chr6:93,811,825–94,447,179, 8 genes, copy number 12: AL356094.1, AL391336.2, AL391336.1, AL157378.1, AL078595.1, AL078595.3, AL078595.2, MTCYBP36.
- chr6:95,917,143–97,140,754, 17 genes, copy number 9: AL034348.1, KRT18P50, FUT9, UFL1-AS1, RN7SL797P, UFL1, FHL5, RPS7P8, RNU4-70P, TYMSP1, AL355143.1, EEF1GP6, AL033379.1, GPR63, NDUFAF4, RN7SL509P, KLHL32.
- chr6:104,017,633–105,454,062, 18 genes, copy number 5 (within-gene range 2–5): R3HDM2P2, NPM1P10, AL357522.1, AL356967.1, HACE1, RNU6-897P, AL357315.1, AL357315.2, LIN28B-AS1, LIN28B, RNU6-1106P, BVES, BVES-AS1, POPDC3, PREP, AL133406.2, AL133406.1, RPL35P3.
- chr7:63,011,463–66,031,544, 149 genes, copy number 5 (broad region; genes not listed).
- chr7:68,266,319–77,198,626, 189 genes, copy number 5–6 (broad region; genes not listed).
- chr7:90,119,299–94,395,608, 75 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr7:104,738,597–105,522,271, 17 genes, copy number 7 (within-gene range 2–7): LHFPL3-AS1, AC091286.1, LHFPL3-AS2, RN7SL8P, AC007384.1, LINC01004, KMT2E-AS1, KMT2E, AC005070.3, SRPK2, AC005070.1, AC005070.2, AC004884.1, RWDD4P1, AC004884.2, RNU6-1322P, PUS7.
- chr7:134,816,543–135,977,359, 24 genes, copy number 5 (within-gene range 3–5): AC083870.1, AGBL3, CYREN, RNF14P4, TMEM140, AC083862.1, AC083862.2, WDR91, AC009542.1, MIR6509, STRA8, SLC23A4P, CNOT4, SDHDP2, NUP205, AC093107.2, AC093107.1, STMP1, RNU6-1154P, SLC13A4, AC091736.1, FAM180A, AC015987.1, MTPN.
- chr7:139,133,744–139,308,236, 6 genes, copy number 7 (within-gene range 2–7): TTC26, AC009220.2, AC009220.3, AC009220.1, MZT1P2, UBN2.
- chr7:149,191,043–149,497,817, 12 genes, copy number 6: AC004890.1, ZNF282, ZNF212, ZNF783, AC004890.3, AC004890.2, AC004941.2, NPM1P12, AC004941.1, AC073314.1, ZNF777, ZNF746.
- chr12:1,529,891–1,918,666, 10 genes, copy number 6–10 (within-gene range 2–10): WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14, CACNA2D4, AC005343.7, LRTM2.
- chr12:3,791,047–4,445,614, 13 genes, copy number 15 (within-gene range 2–15): PARP11, OTUD4P1, PARP11-AS1, AC084375.1, HSPA8P5, AC007207.1, CCND2-AS1, CCND2, AC008012.1, TIGAR, AC006122.1, FGF23, FGF6.
- chr12:14,914,039–15,348,675, 8 genes, copy number 20 (within-gene range 2–20): ERP27, ARHGDIB, PDE6H, LINC01489, RERG, RERG-IT1, RERG-AS1, METTL8P1.
- chr12:17,066,368–17,167,790, 4 genes, copy number 6: AC092793.1, RNU6-837P, AC092110.1, RPL7P40.
- chr12:20,962,768–21,942,529, 19 genes, copy number 7–16: SLCO1B7, AC022335.1, SLCO1B1, SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB, AC010197.1, AC010185.1, KCNJ8, ABCC9, AC008250.1, AC008250.2.
- chr12:22,573,425–23,191,587, 9 genes, copy number 6–18 (within-gene range 2–18): LRRC34P1, AC087241.1, AC087241.2, ETNK1, AC084816.1, RPS27P22, AC084819.1, AC087258.1, AC087235.2.
- chr12:24,566,964–25,108,334, 12 genes, copy number 9 (within-gene range 2–9): LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2.
- chr12:28,821,975–29,497,686, 12 genes, copy number 11: AC022081.1, AC024255.1, AC012150.1, FAR2, AC012150.2, AC009318.4, AC009318.1, AC009318.3, AC009318.2, ERGIC2, OVCH1-AS1, OVCH1.
- chr12:31,073,860–31,591,136, 20 genes, copy number 5 (within-gene range 2–5): DDX11, SNORA75, AC008013.3, AC024940.1, AC024940.4, AC024940.2, MREGP1, AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6, DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2.
- chr12:32,072,734–32,383,633, 6 genes, copy number 10 (within-gene range 2–10): AC048344.2, AC048344.3, AC048344.1, BICD1, AC048344.4, AC016954.1.
- chr12:39,626,167–40,369,285, 9 genes, copy number 16 (within-gene range 3–16): C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1.
- chr12:42,454,720–42,646,547, 7 genes, copy number 16 (within-gene range 2–16): Y_RNA, PRICKLE1, AC079601.1, AC079600.3, LINC02402, AC079600.2, AC079600.1.
- chr12:47,661,249–47,943,048, 17 genes, copy number 16 (within-gene range 2–16): RPAP3, AC004241.3, AC004241.1, ENDOU, AC004241.5, AC004241.2, RAPGEF3, SLC48A1, AC004241.4, HDAC7, AC004466.1, AC004466.3, AC004466.2, LINC02354, VDR, AC121338.1, AC121338.2.
- chr12:48,350,945–48,500,961, 10 genes, copy number 18 (within-gene range 2–18): AC090115.1, AC024257.4, OR5BT1P, OR5BJ1P, OR8S21P, OR8T1P, ANP32D, C12orf54, AC089987.2, RPS10P20.
- chr12:48,627,879–48,682,238, 6 genes, copy number 5: OR11M1P, KANSL2, SNORA2C, MIR1291, SNORA2A, SNORA2B.
- chr12:55,221,025–56,190,284, 75 genes, copy number 7–12 (within-gene range 2–12) (broad region; genes not listed).
- chr12:56,663,341–56,787,790, 6 genes, copy number 9: PTGES3, RN7SL809P, NACA, AC117378.1, PRIM1, HSD17B6.
- chr12:57,693,955–58,098,013, 29 genes, copy number 16 (within-gene range 2–16): OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1.
- chr12:67,929,235–68,234,686, 6 genes, copy number 12 (within-gene range 2–12): LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1.
- chr12:68,552,995–69,460,724, 31 genes, copy number 9–20: RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373.
- chr12:90,280,894–91,058,024, 9 genes, copy number 11: LINC02392, LINC02822, AC084365.1, AC112481.2, AC112481.1, CCER1, LINC00615, EPYC, KERA.

Autosomal genes at a single copy (total copy number 1): 23. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
